CPTAC case C3N-03015 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b3e9d84f-f513-47d5-b3dd-c940ecb19e16

Demographics
Sex at birth: male; Race: white; Year of birth: 1956; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 61.0 years (22,292 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,815 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,815 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 24; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 429 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 660 days (1.8 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 1,032 days (2.8 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,032 days (2.8 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,493 days (4.1 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,815 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 85 kg; Height: 164 cm; BMI: 31.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03015-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 137 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03015-21: Section location: Floor of Mouth; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3N-03015-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 142 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03015-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
